Surgical pathology report (de-identified scan), TCGA case TCGA-55-8206, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-55-8206-01A (Primary Tumor).

[page 1 of 3]
Results

GROSS AND MICROSCOPIC SURGICAL PANEL

Specimen Information

Collection Date and Time

Component Results

SURGICAL PANEL:

SURGICAL PATHOLOGY REPORT

Final Report

DIAGNOSIS

A) LUNG, RIGHT UPPER LOBE, LOBECTOMY:

1. Moderately differentiated adenocarcinoma forming a mass measuring 2.3 x 2.2 x 2.2 cm
2. Tumor abuts but does not invade visceral pleura
3. Benign bronchial and vascular resection margins
4. Three benign variably anthracotic lymph nodes
5. Histologically unremarkable surrounding pulmonary parenchyma

B) HILAR LYMPH NODE, EXCISION:

1. Benign anthracotic lymph node
2. No evidence of metastatic carcinoma

T LUNG CANCER STAGING PARAMETERS***

Case number: Patient name:

Final TNM: pT1bN0M0

stage: IA

MACROSCOPIC

SPECIMEN TYPE

Lobectomy

TUMOR SITE

Right Lung-Upper Lobe

TUMOR SIZE

2.3 X 2.2 X 2.2 cm

TUMOR FOCALITY

Unifocal

MICROSCOPIC

HISTOLOGIC TYPE

Adenocarcinoma

HISTOLOGICAL GRADE

G2: (moderately differentiated) of G4

VISCERAL PLEURAL INVASION

Not identified

LYMPHATIC VASCULAR INVASION

Absent

TREATMENT EFFECT

Not applicable

TUMOR EXTENSION

Not applicable

MARGINS

Uninvolved by tumor (Bronchial)

Distance of tumor from closest margin is 4 cm

[page 2 of 3]
PATHOLOGIC STAGING

EXTENT OF INVASION

pT1b. [Tumor greater than 2 cm, but 3 cm or less in greatest dimension, surrounded by lung or visceral pleura, without bronchoscopic evidence of invasion more proximal than the lobar bronchus (ie, not in the main bronchus)]

REGIONAL LYMPH NODES

pN0. (No regional lymph node metastasis)

Total nodes: 4

Total positive nodes: 0

N1 nodes: 4

N1 positive nodes: 0

DISTANT METASTASIS

pM0. (No distant metastasis)

PATHOLOGIC STAGE Summary

Final TNM: pT1bN0M0

stage: IA

** The pathologic stage presumes no distant metastasis.

***LUNG ANCILLARY TESTING PROTOCOL ***

Case number: Patient name:

HISTOLOGIC TYPE

Adenocarcinoma

STAGE IV STATUS

Stage IV status is undetermined

TISSUE BLOCK AVAILABLE FOR ANCILLARY TESTING

A7

COMMENT

This patient's sample does not meet criteria* for reflex EGFR and ALK testing. No fresh tissue is available for ancillary testing. The block identified above will be stored in pathology for 10 years for possible future ancillary testing. Please call for any ancillary testing requests.

* EGFR and ALK reflex testing criteria:
Stage IV disease (histologically proven or clinically suspicious)
Adenocarcinoma or TTF-1 positive adenosquamous cell carcinoma.

Attending Pathologist:

CLINICAL INFORMATION

Adenocarcinoma

SPECIMEN/GROSS DESCRIPTION

A) SOURCE: Lung, right upper lobe

Received fresh labeled "right upper lobe lung" and consists of a 14 x 11 x 2.5 cm lobe of lung. The bronchial margin is taken en face and submitted on one chuck for frozen section diagnosis.

INTRAOPERATIVE PATHOLOGY CONSULTATION WITH FROZEN SECTION: "Bronchial margin negative" is rendered by

On cut section, there is a palpable 2.3 x 2.2 x 2.2 cm mass in the upper portion of the lobe. It puckers the pleural surface which has been inked black. The mass is 4 cm from the nearest bronchial margin. The remainder of the parenchyma is spongy tan-pink with very mild anthracosis.

Part of the tissue is taken for possible ancillary study.

[page 3 of 3]
[REDACTED]

Representative sections are submitted in 10 cassettes labeled:

1. Frozen section
2. Vascular margins
3. Hilar lymph nodes
- 4-7. Tumor to pleural surface in normal parenchyma
- 8-10. Random normal parenchyma remote from tumor
- [REDACTED]

B) SOURCE: Hilar lymph node

Labeled "hilar lymph node" is a 0.7 cm anthracotic lymph node. The specimen is submitted in toto in one cassette.

This case is accessioned in [REDACTED]

Gross dictation by: [REDACTED]

MICROSCOPIC

A,B) The microscopic appearance substantiates the diagnosis. An elastic stain is obtained on block A5 to assess for possible visceral pleural involvement. Dictation by: [REDACTED]

[REDACTED]

COLLECTED: [REDACTED] ACCESSIONED: [REDACTED] SIGNED: [REDACTED]

Lab and Collection

GROSS AND MICROSCOPIC SURGICAL PANEL [REDACTED]
Information

Lab and Collection

Result History

GROSS AND MICROSCOPIC SURGICAL PANEL [REDACTED]
Report

Order Result History

Lab Status

Order Complete [3]

[REDACTED]

Result Information

Result Date and Time

Status

Final result

Provider Status

Reviewed

Lab Information

Lab

[REDACTED]

Order Details

Parent Order ID

Child Order ID

Entry Date

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 5056cd04-2071-40b2-9613-52224f0e433a (TCGA-55-8206.6A62AEFF-3381-4AE5-8BB5-789542F8CE3C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).